Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3858, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3858-01A (Primary Tumor).

Diagnosis:

In I), there is a benign lesion in the sense of a hyperplastic polyp, in II) is an adenocarcinoma of the colon (Block A) of poor differentiation with infiltration of the muscularis and vessels (G3, pT2, L1, V1).

Tumor classification:

ICDO-DA M8140/3

G3

pT2, L1, V1, pN0 (0 of 12), locally R0

Source: NCI Genomic Data Commons file 613a38ea-bc91-489d-bc6c-26c814684f08 (TCGA-AA-3858.76997550-47ED-4958-96AA-AC0CDEC9F134.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).